Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A5DU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A5DU-01A (Primary Tumor).

[page 1 of 3]
Patient:

Referring Physician:

Gender: F

Ref#:

Hosp#:

Provider Group :

Date of Service:

Date Received:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. LEFT RENAL MASS, PARTIAL NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA (TYPE 1), FUHRMAN NUCLEAR GRADE 2.
- TUMOR IS CONFINED TO KIDNEY AND MEASURES 2.2 CM IN GREATEST DIMENSION.
- TUMOR FOCALLY INVOLVES CAUTERIZED PARENCHYMAL RESECTION MARGIN.
- NO LYMPHOVASCULAR INVASION IDENTIFIED.
- ADJACENT BENIGN RENAL PARENCHYMA PRESENT.

B. BASE OF LEFT RENAL MASS, BIOPSY:

- MINUTE FRAGMENT OF CAUTERIZED BENIGN RENAL PARENCHYMA.
- NEGATIVE FOR MALIGNANCY.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Papillary renal cell carcinoma, Fuhrman nuclear grade 2.

Primary tumor: pT1a.

Regional lymph nodes: pNX.

Distant metastasis: N/A.

Stage: I.

Lymphovascular invasion: Not identified.

Margin status: R1, focally positive.

ICD-6-3

Carcinoma, papillary
renal cell 8260/3

Site: @ Kidney NBS C64.9

9/12/24/12

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Case #:

Page 1

This report continues... (FINAL)

Acct No.

Patient Name -

[page 2 of 3]
Patient:

Case #

Procedure:	Partial nephrectomy.
Laterality:	Left kidney.
TUMOR FEATURES:	
Tumor size:	2.2 cm in greatest dimension.
Tumor focality:	Unifocal.
Extent of tumor:	Tumor confined to kidney.
Histologic type:	Papillary renal cell carcinoma (type 1).
Sarcomatoid features:	Not identified.
Histologic grade:	Fuhrman nuclear grade 2.
Microscopic tumor extension:	Tumor confined to kidney.
MARGINS:	
Parenchymal resection margin:	Focally positive.
LYMPH NODES:	N/A.
PATHOLOGIC STAGING:	
Primary tumor:	pT1.
Regional lymph nodes:	N/A.
Distant metastasis:	N/A.
Stage:	I.
Pathologic findings in non-neoplastic kidney:	None.

Source of Specimen:

Case #

Page 2

This report continues... (FINAL)

Acct No. -

Patient Name -

[page 3 of 3]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

- A. Kidney; Left renal mass
B. Base of left renal mass

Clinical History/Operative Dx:

Left renal mass

Gross Description:

A. Single specimen designated left renal mass - Initially received in a fresh state for Oncogenotyping studies, is an ovoid and lobular portion of red-tan, soft tissue, 3.2 x 2.2 x 2.2 cm and 5 grams. The likely surgical margin is marked blue. The superficial surface is glistening with light pink-yellow changes, now marked orange. Sectioning demonstrates a well circumscribed, softened, partially degenerated, yellow-tan tumor mass, measuring 2.2 x 2.0 x 1.8 cm. The tumor mass abuts the deep surgical margin, and overlying renal capsule. The tumor partially abuts or approaches within 0.3 cm of the peripheral surgical margins. The specimen is entirely submitted for microscopic evaluation, in a sequential fashion in A1-A6.

B. Part B designated base of left renal mass. Received in formalin is a single discrete fragment of partially cauterized light pink and gray soft tissue measuring 0.6 x 0.4 x 0.1 cm. The fragment is submitted within a filter bag in B1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Intradepartmental consultation: [REDACTED] has reviewed a representative slide of tumor and concurs with the presence of a positive margin.

Criteria	10/12/2012	Yes	No
MMAX Discrepancy			✓
Distal Synchronous Primary Noted			✓

Case #:

Page 3

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file babcd789-9e18-40a8-b1b0-b2560641e660 (TCGA-A4-A5DU.2E0238CF-4E3F-4838-A7EC-804E367E6472.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).